Gene-level copy-number profile of tumor specimen C3L-00094-03 from CPTAC case C3L-00094, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 70.0 years (25,560 days).
Specimen C3L-00094-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 82e44cfc-98d6-4ebc-93d0-3fa25fc50477.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00094-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,757 have no estimate.
https://portal.gdc.cancer.gov/files/b4b36a04-5582-4d4a-8709-be25ff495ecc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 472; copy number 2: 671; copy number 3: 18,835; copy number 4: 21,090; copy number 5: 6,739; copy number 6: 10,172; copy number 7: 428; copy number 8: 78; copy number 10: 13; copy number 11: 47; copy number 12: 64; copy number 13: 6; copy number 15: 64; copy number 19: 115; copy number 36: 66; copy number 67: 5.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 380 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,573,801–248,645,278, 6 genes, copy number 10: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr7:70,837,738–71,713,600, 5 genes, copy number 10–12: AC073873.1, GALNT17, MIR3914-1, MIR3914-2, RN7SKP75.
- chr14:18,333,726–18,412,264, 3 genes, copy number 10: CR383658.1, RNU6-458P, CR383658.2.
- chr14:21,782,993–22,190,713, 41 genes, copy number 11: TRAV7, TRAV8-1, TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:22,202,583–22,272,563, 6 genes, copy number 11: TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1.
- chr14:22,766,522–37,596,059, 319 genes, copy number 12–67 (within-gene range 3–67) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
